Somatic mutation profile of tumor specimen TCGA-DZ-6134-01A (aliquot TCGA-DZ-6134-01A-11D-1961-08) from TCGA case TCGA-DZ-6134, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 69.9 years (25,529 days).
Specimen TCGA-DZ-6134-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7286aa72-4fcc-4aa7-aa7e-fc8eebf99ad0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DZ-6134-10A (Blood Derived Normal), aliquot TCGA-DZ-6134-10A-01D-1962-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8cbdd01a-4624-479e-96e9-20d75306db65

The open-access MAF lists 45 somatic variants for this specimen: 32 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 12, Nonsense Mutation 2, Splice Region 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 21/77 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACTA1 | c.550G>A p.G184S | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64203101; called by muse, mutect2, varscan2
- ATF7 | c.1442C>T p.S481L (on ENST00000548446 / NM_001366555.2; = p.S470L on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1461064502, COSV60642777; called by muse, mutect2, varscan2
- ATRNL1 | c.625A>C p.N209H | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100746904, COSV61800923; called by muse, mutect2
- BTBD6 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as rs1170100270, COSV59267305; called by muse, mutect2, varscan2
- C20orf141 | c.358C>T p.Q120* | Nonsense Mutation (SNP) | VAF 9/78 reads (12%) | catalogued as rs1009058010, COSV100730207; called by muse, mutect2, varscan2
- CAMK1D | c.134C>T p.T45I | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV66609354; called by muse, mutect2, varscan2
- CAPN5 | c.784C>T p.H262Y (on ENST00000456580; = p.H222Y on NM_004055.5) | Missense Mutation (SNP) | VAF 20/314 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.035); catalogued as COSV53686832; called by muse, mutect2
- DHDH | c.835T>G p.F279V | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as COSV55481812; called by muse, varscan2
- DHDH | c.859T>A p.Y287N | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55481822; called by muse, varscan2
- DIP2C | c.3296C>T p.A1099V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1356539941, COSV55151694; called by muse, mutect2, varscan2
- EEF2KMT | c.452A>T p.E151V | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV69863299; called by muse, mutect2
- FZD1 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV55309681; called by muse, mutect2, varscan2
- GPR55 | c.389G>A p.S130N | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs766757239, COSV67407410; called by mutect2, varscan2
- GRM4 | c.654G>A p.W218* | Nonsense Mutation (SNP) | VAF 15/59 reads (25%) | catalogued as COSV65211937; called by muse, mutect2, varscan2
- HSDL2 | c.533A>G p.Y178C | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52714162; called by muse, mutect2
- MLX | c.333T>C p.D111= | Splice Region (SNP) | VAF 5/20 reads (25%) | catalogued as COSV53816622; called by muse, mutect2, varscan2
- NINL | c.1646C>A p.A549E | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1261202062, COSV54000416, COSV99626257; called by muse, mutect2, varscan2
- NINL | c.1645G>T p.A549S | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as COSV54000425; called by muse, mutect2, varscan2
- NR2C2AP | c.84dup p.H29Tfs*7 | Frame Shift Ins (INS) | VAF 17/90 reads (19%) | catalogued as rs780246694; called by mutect2, varscan2
- OR1D5 | c.367T>A p.Y123N | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV73859497; called by muse, mutect2, varscan2
- PCF11 | c.1774A>G p.K592E | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.971); catalogued as COSV53529206; called by muse, mutect2, varscan2
- POGZ | c.2755C>T p.P919S | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51851001; called by muse, mutect2, varscan2
- SLC43A1 | c.859A>T p.N287Y | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.516); catalogued as COSV53558211; called by muse, mutect2, varscan2
- SMARCC2 | c.3316A>G p.I1106V | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as COSV53237900; called by muse, mutect2, varscan2
- SRRM1 | c.1696C>T p.P566S | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.992); catalogued as rs777541603, COSV60475994; called by muse, mutect2, varscan2
- STAT1 | c.838T>A p.L280M | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV61189745; called by muse, mutect2, varscan2
- TP53TG5 | c.234G>C p.K78N | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.587); catalogued as COSV65577147; called by muse, mutect2
- WNT10A | c.554G>A p.G185D | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.922); catalogued as COSV51461983, COSV51462885; called by muse, mutect2, varscan2
- ZCWPW1 | c.338A>G p.Q113R | Missense Mutation (SNP) | VAF 85/219 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV61248484; called by muse, mutect2, varscan2
- ZNF568 | c.1543T>C p.S515P | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs201711551; called by muse, mutect2, varscan2
- RDM1 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 20/340 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2
- ALAD | c.777C>T p.D259= | Silent (SNP) | VAF 24/105 reads (23%) | catalogued as COSV52958412; called by muse, mutect2, varscan2
- C20orf141 | c.357G>T p.L119= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as COSV100730206; called by muse, mutect2, varscan2
- CRIP3 | c.216A>G p.V72= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as COSV51483435; called by muse, varscan2
- GCH1 | c.723G>A p.R241= | Silent (SNP) | VAF 22/136 reads (16%) | catalogued as COSV54301471; called by muse, mutect2, varscan2
- GFPT2 | c.624C>T p.V208= | Silent (SNP) | VAF 29/153 reads (19%) | catalogued as COSV53807432; called by muse, mutect2, varscan2
- MYH2 | c.5454C>T p.I1818= | Silent (SNP) | VAF 76/211 reads (36%) | catalogued as COSV55434638, COSV99820422; called by muse, mutect2, varscan2
- PDIA6 | c.1035T>A p.L345= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV55349998; called by muse, mutect2
- PTCD1 | c.1341C>T p.A447= | Silent (SNP) | VAF 46/140 reads (33%) | catalogued as rs756690997, COSV52862321; called by muse, mutect2, varscan2
- RHBDL3 | c.822C>T p.V274= | Silent (SNP) | VAF 20/159 reads (13%) | catalogued as rs749339761, COSV99284022; called by muse, mutect2, varscan2
- SERPINE1 | c.1152G>C p.V384= | Silent (SNP) | VAF 24/179 reads (13%) | catalogued as COSV56169137, COSV56171283; called by muse, mutect2, varscan2
- TRGV5 | c.54A>G p.K18= | Silent (SNP) | VAF 30/116 reads (26%) | called by muse, mutect2, varscan2
- ZSCAN18 | c.885C>T p.A295= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as rs200010643, COSV53731415; called by mutect2, varscan2
- CD99 | c.67+383G>A | Intron (SNP) | VAF 10/29 reads (34%) | catalogued as COSV101152915; called by muse, mutect2, varscan2
